Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6627, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6627-01A (Primary Tumor).

SPECIMENS:

A. TERMINAL ILEUM AND RIGHT COLON

DIAGNOSIS:

- A. RIGHT COLON AND TERMINAL ILEUM, RESECTION:
- INFILTRATING MODERATELY DIFFERENTIATED COLON ADENOCARCINOMA (2.2 CM) INVOLVING THE SUBSerosa.
- SIXTEEN BENIGN LYMPH NODES (0/16). SEE TEMPLATE
- SURGICAL MARGINS ARE NOT INVOLVED
- MULTIPLE HYPERPLASTIC POLYPS AND SMALL TUBULAR ADENOMA.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Right hemicolectomy
Tumor Site:	Ascending colon
Tumor Configuration:	Ulcerating with indurated edge
Tumor Size:	2.2 cm
Histological Type:	Adenocarcinoma
Histological Grade:	Moderate-poorly differentiated
Extent of Invasion:	Subserosa
Margins:	Uninvolved
Distance to Closest Margin:	0.6 cm from radial margin
Angiolymphatic Invasion:	Absent
Perineural Invasion:	Absent
Additional Findings:	Hyperplastic polyps and minute tubular adenoma
Extent of Resection:	R0: Complete
Lymph Nodes:	Negative: 0/16
Implants:	Absent
Pathological Stage:	pT3a N0 MX

SPECIMEN(S):

A. TERMINAL ILEUM AND RIGHT COLON

CLINICAL HISTORY:

Not given

GROSS DESCRIPTION:

A. TERMINAL ILEUM AND RIGHT COLON

Received fresh and labeled as "terminal ileum and right colon". Received is a closed segment of colon and terminal ileum measuring 26.4 cm in length. There is a constricted portion of the right colon located at the mid segment. This entire segment is inked blue. The terminal ileum measures approximately 4.6 x 4.1 cm and the right colon measures 22.0 cm in length and 6.0 cm in diameter. There is an ulcerated tumor mass measuring 2.2 x 2.2 x 0.6 cm which extends through the muscularis propria. The tumor is situated in the colon and is located 11.0 cm from the proximal margin and 13.0 cm from the distal colonic margin. There are several polyps present throughout the right colon ranging in size from 0.1 to 0.7 cm. Sections are taken for tissue procurement and gross photograph was also taken.

Representative sections are submitted as follows:

- A1: shaved sections of proximal margin
- A2: shaved sections of distal margin
- A3-A11: mass, including deep margin
- A12: polyps
- A13: normal-appearing colonic mucosa
- A14-A17: possible lymph nodes
- A18: normal-appearing tissue from ileum

Source: NCI Genomic Data Commons file 257a1397-f9fb-46f2-9267-22ed385e2c15 (TCGA-G4-6627.E8744B51-CCED-496B-9746-9F06FF93A01E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).